Surgical pathology report (de-identified scan), TCGA case TCGA-AL-3473, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AL-3473-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left renal mass.

Source of Specimen(s):

- 1: Para aortic Lymph Node
- 2: Kidney resection with Adrenal gland

Gross Description:

Received in two parts.

Source of tissue: 1. Labeled #1, "para-aortic lymph nodes"

Gross Description: Received fresh labeled para-aortic lymph nodes" consists of multiple soft yellow-tan irregular fibrofatty tissue fragments measuring 5.5 x 4.5 x 2 cm in aggregate. The specimen is sectioned to reveal multiple soft to firm lymph nodes measuring from 0.3 up to 2.2 cm in greatest dimension. The lymph nodes are entirely submitted in 1A-1D.

Designation of Sections: 1A one bisected lymph nodes. 1B-1D multiple additional lymph nodes.

Source of tissue: 2. Labeled #2, "left kidney"

Gross Description: Received fresh labeled, left kidney" consists of a kidney with surrounding perinephric fat weighing 1,080 grams and measuring 22 x 18 x 9.5 cm. The attached ureter measures 11.5 cm in length and 0.3 cm in diameter. The ureter is sectioned to show a homogeneous, soft tan-pink smooth mucosal lining with no ulcerations or polyps present. The specimen is bisected to show a 12.5 x 8.5 x 6 cm kidney. A 7.5 x 6.5 x 5 cm ill-defined variegated midpole mass is identified at approximately 0.5 cm from the closest superior pole capsule. The mass also obliterates approximately 90% of the renal pelvis. Representative sections are submitted in 2A-2I.

Designation of Sections: 2A ureteral and vascular margins. 2B-2D tumor closest to capsule. 2E-2F tumor with adjacent uninvolved parenchyma. 2G-2I tumor with surrounding fat margin inked black.

Final Diagnosis:

1. Paraaortic lymph nodes, excision:
- Thirty-three lymph nodes with no tumor seen, (0/33).
2. Left kidney, nephrectomy:

[page 2 of 2]
- Papillary renal cell carcinoma, type 2, (7.5 cm); definitive extrarenal extension not seen.
- Vascular and ureteral margins with no tumor seen.

(pT2N0Mx)

Procedures/Addenda

FC Cytogenetics Solid Tumor
Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Left Renal Mass

KARYOTYPE: Abnormal mosaic [redacted] karyotype:
45,X,-Y[3]/45
49,XY,+7[cp5]/46,XY[15]

RESULTS: The renal mass was harvested after eight and ten days in culture. The chromosomes from 23 metaphases were counted and analyzed, and four of these metaphases were karyotyped by G-banding. Three cells had a modal chromosome number of 45 and were missing the Y chromosome. Five cells had a modal chromosome number of 47 and contained an extra copy of chromosome 7. Fifteen cells had a modal chromosome number of 46 and appeared to have a normal karyotype.

Procedures/Addenda

Addendum Date Ordered: Addendum Diagnosis
The nuclear grade of the tumor is equivalent to Fuhrman grade 3.

Source: NCI Genomic Data Commons file 97520dc5-2f12-4278-9859-2d3f82b2e7b3 (TCGA-AL-3473.CB8E89A1-391D-408D-9A24-5E250AFD6B83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).